Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GS, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GS-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Department of Pathology,

Physician:

Accession.

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) TISSUE RIGHT INFERIOR THYROID POLE:

Fragment of parathyroid tissue, no tumor present.

(B) TISSUE, LEFT THYROID, SUPERIOR POLE:

Fragment of parathyroid tissue, no tumor present.

(C) TOTAL THYROID:

PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Bilateral

Multi-focal: Yes

Size = 1.6 cm, left lobe and 0.4 cm right

Extrathyroidal extension: PRESENT (PART D)

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE LYMPH NODE (1/1)

Location: perithyroidal

Extracapsular extension: Absent

(D) TISSUE RIGHT THYROID BED:

PAPILLARY THYROID CARCINOMA AND ASSOCIATED NORMAL THYROID TISSUE.
EXTENSION INTO SOFT TISSUE PRESENT

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, nos C73.9 11/30/11

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) TISSUE RIGHT INFERIOR THYROID POLE - A fragment of red-brown soft tissue (0.2 x 0.1 x 0.1 cm). Entirely submitted for frozen in A.

*FS/DX: CELLULAR PARATHYROID TISSUE.

(B) TISSUE, LEFT THYROID, SUPERIOR POLE - A 0.2 cm fragment of soft tissue. Entirely submitted for frozen section.

*FS/DX: PARATHYROID TISSUE.

(C) TOTAL THYROID - A total thyroidectomy has an enlarged right lobe (4.2 x 2.5 x 1.6 cm) with a centrally located, soft, pink-red friable nodule (1.6 x 1.5 x 1.5 cm) surrounded by thyroid parenchyma.

The isthmus (1.0 x 2.0 x 0.3 cm) is unremarkable.

The left lobe (3.2 x 2.0 x 0.8 cm) has a firm, oval nodule at the inferior pole (1.2 x 0.6 x 0.8 cm) which on cut surface has a firm, yellow core. Representative sections are submitted.

[page 2 of 2]
Surgical Pathology Report

Department of Pathology

DOB:

Sex: F

Physician:

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

SECTION CODE: C1, representative of unremarkable right lobe superior; C2-C5, nodule from middle of right lobe; C6, representative of inferior right lobe; C7, sections of isthmus and lymph node; C8, representative of superior left unremarkable thyroid; C9, C10, inferior left thyroid nodule.

(D) TISSUE RIGHT THYROID BED AT RLN - Four separate portions of soft red tissue containing a firm tan nodule (0.5 x 0.4 x 0.2 cm in aggregate). Entirely submitted in D.

CLINICAL HISTORY

Papillary thyroid carcinoma.

SNOMED CODES

T-B6000, M-80503, T-C4200, M-80506, T-B7000

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Released by:

Page 2 of 2	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file 29b34ed2-f48a-41d2-bb54-f5b22a2ad9bb (TCGA-EL-A3GS.1FE3CE73-2A35-4436-A60D-7FEEE216B7B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).